Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A01I, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A01I-01A (Primary Tumor).

TCGA #:

Sample ID #:

Diagnosis:

Resected section of colon (left hemicolon) with two colon carcinomas characterized histologically as colorectal adenocarcinoma of similarly moderate differentiation, one located at a distance of 3.5 cm from the resection margin, with a diameter of 3.5 cm at the widest point, and the other located 18 cm from the same resection margin, and measuring 3.3 cm at the widest point, one at the base of a tubulovillous adenoma with severe epithelial dysplasia (synonymous: profound intraepithelial neoplasia), and the other clearly at the base of a tubular adenoma with severe epithelial dysplasia (synonymous: profound intraepithelial neoplasia). Invasive spread of the tumor to the layers of the muscularis propria.

Mucous membrane of the colon with a tubulovillous adenoma of the colon mucosa with severe epithelial dysplasia (synonym: profound intraepithelial neoplasia) and two tubular adenomas of the colon mucosa, with moderate epithelial dysplasia (synonym: mild intraepithelial neoplasia).

Tumor-free oral and aboral resection margin.

36 local lymph nodes are tumor-free with uncharacteristically reactive changes.

Stage of tumor of both colon carcinomas: pT2 pN0 (0/36) L0 V0; G2 R0.

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: sigmoid colon (per CACF) C18.7

per 3/30/11

HIIPA Discrepancy		☒

Source: NCI Genomic Data Commons file eff9f41f-764f-4086-8ed8-89665938920d (TCGA-AA-A01I.51A15A40-E611-49C3-AB69-638871664D86.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).